Somatic mutation profile of tumor specimen TCGA-BW-A5NO-01A (aliquot TCGA-BW-A5NO-01A-11D-A27I-10) from TCGA case TCGA-BW-A5NO, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 50.7 years (18,510 days).
Specimen TCGA-BW-A5NO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1005666a-f2bb-4813-a485-67abed80826b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BW-A5NO-10A (Blood Derived Normal), aliquot TCGA-BW-A5NO-10A-01D-A27I-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40808cde-b0be-48e4-9c03-753d40dc6b71

The open-access MAF lists 132 somatic variants for this specimen: 97 protein-altering or splice-affecting, 29 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 29, Nonsense Mutation 6, 3'UTR 5, Splice Site 4, Frame Shift Del 3, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP27A1 | c.1213C>T p.R405W | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs573951598, CM004249, COSV51468115; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACACB | c.2357T>A p.M786K | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV58133885; called by muse, mutect2, varscan2
- ADAMDEC1 | c.831A>G p.I277M | Missense Mutation (SNP) | VAF 93/118 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56475113; called by muse, mutect2
- ADGRE1 | c.841C>G p.P281A | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.525); catalogued as COSV51675164; called by muse, mutect2
- ARHGEF12 | c.3876G>C p.Q1292H | Missense Mutation (SNP) | VAF 5/124 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.548); catalogued as COSV63103678; called by muse, mutect2
- ASB4 | c.31T>C p.S11P | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV57507947; called by muse, mutect2, varscan2
- ATG10 | c.531G>T p.K177N | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as rs1203130917, COSV56425658, COSV99967213; called by muse, mutect2, varscan2
- ATP5F1C | c.204A>G p.I68M | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV59621543; called by muse, mutect2, varscan2
- BTBD9 | c.140T>C p.F47S | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58425313; called by muse, mutect2, varscan2
- C1orf87 | c.498C>A p.S166R | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64597053; called by muse, mutect2, varscan2
- CACHD1 | c.2684A>G p.D895G | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV51552749; called by muse, mutect2, varscan2
- CACNA1I | c.641T>A p.L214Q | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60807466; called by muse, mutect2, varscan2
- CCDC141 | c.3107G>A p.G1036E | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV55371199, COSV55373032, COSV55376755; called by muse, mutect2, varscan2
- CDH9 | c.1180G>T p.E394* | Nonsense Mutation (SNP) | VAF 42/77 reads (55%) | catalogued as COSV50279767; called by muse, mutect2, varscan2
- CIT | c.1322C>A p.P441H | Missense Mutation (SNP) | VAF 5/105 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV55867731; called by muse, mutect2
- CLTCL1 | c.2848A>T p.R950* | Nonsense Mutation (SNP) | VAF 36/103 reads (35%) | catalogued as COSV54229904; called by muse, mutect2, varscan2
- COLGALT2 | c.532C>T p.L178F | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs1307243534, COSV62728624; called by muse, mutect2, varscan2
- CR1 | c.5596C>A p.L1866I | Missense Mutation (SNP) | VAF 84/206 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.076); catalogued as COSV65458053; called by muse, mutect2, varscan2
- CUL5 | c.346A>T p.I116F | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.163); catalogued as COSV67608819; called by muse, mutect2
- CYLC2 | c.573A>T p.K191N | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as COSV66337420; called by muse, mutect2, varscan2
- DENND2A | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 36/91 reads (40%) | catalogued as COSV52050348, COSV52050979; called by muse, mutect2, varscan2
- DNAH5 | c.3629C>T p.T1210I | Missense Mutation (SNP) | VAF 92/216 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV54222378; called by muse, mutect2, varscan2
- DNAJC19 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.516); catalogued as COSV66846253; called by muse, mutect2, varscan2
- EID1 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.694); catalogued as COSV60111992; called by muse, mutect2
- EMB | c.752A>T p.E251V | Missense Mutation (SNP) | VAF 83/258 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.238); catalogued as COSV57482037; called by muse, mutect2, varscan2
- EML1 | c.674G>T p.W225L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV51744737; called by muse, mutect2, varscan2
- FASTKD3 | c.806A>T p.K269I | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as COSV52943499; called by muse, mutect2
- FILIP1 | c.1108G>T p.E370* | Nonsense Mutation (SNP) | VAF 25/104 reads (24%) | catalogued as COSV52728885; called by muse, mutect2, varscan2
- FIP1L1 | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.855); catalogued as COSV100184712, COSV60996249; called by muse, mutect2, varscan2
- GARNL3 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV59226028; called by muse, mutect2, varscan2
- GCNA | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 87/124 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV65466653; called by muse, mutect2, varscan2
- GHSR | c.1067C>A p.S356Y | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.231); catalogued as COSV53838882; called by muse, mutect2, varscan2
- GOSR2 | c.113G>A p.S38N (on ENST00000393456 / NM_001321134.1; = p.S56N on NM_004287.5) | Missense Mutation (SNP) | VAF 96/237 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99846345; called by muse, varscan2
- H2BC5 | c.129C>G p.Y43* | Nonsense Mutation (SNP) | VAF 12/99 reads (12%) | catalogued as COSV56800984, COSV99175227; called by muse, mutect2, varscan2
- HAUS8 | c.991C>G p.Q331E | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs762500112, COSV53726040; called by muse, mutect2, varscan2
- HHIP | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.282); catalogued as rs199961348, COSV56838801; called by muse, mutect2, varscan2
- ITPR3 | c.5091C>A p.N1697K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.165); catalogued as COSV65408678; called by muse, mutect2, varscan2
- LILRA2 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.899); catalogued as rs1428777987, COSV52190178, COSV52191195; called by muse, mutect2
- LPL | c.412T>A p.F138I | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60931122; called by muse, mutect2
- LRP12 | c.1370A>C p.H457P | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV52628458; called by muse, mutect2, varscan2
- LRP1B | c.12844C>A p.P4282T | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV67215613; called by muse, mutect2
- LRRC4 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1173588157, COSV50813874; called by muse, mutect2, varscan2
- LSAMP | c.295C>G p.Q99E | Missense Mutation (SNP) | VAF 98/255 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.173); catalogued as rs1184465262, COSV61289207; called by muse, mutect2, varscan2
- LYPD6 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); catalogued as rs1483933287, COSV61940055, COSV61941991; called by muse, mutect2, varscan2
- MAGEA12 | c.511C>A p.R171S | Missense Mutation (SNP) | VAF 229/290 reads (79%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV63294552, COSV63294755; called by muse, mutect2, varscan2
- MFN2 | c.2128C>G p.L710V | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52422292; called by muse, mutect2, varscan2
- MRPL2 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.431); catalogued as rs1259187369, COSV52435540; called by muse, mutect2
- MTMR14 | c.614del p.Y205Sfs*10 | Frame Shift Del (DEL) | VAF 56/149 reads (38%) | catalogued as COSV56005365; called by mutect2, pindel, varscan2
- MUC16 | c.36145G>T p.V12049L | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.679); catalogued as COSV67463434; called by muse, mutect2
- MX2 | c.1172G>T p.G391V | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV58096364; called by muse, mutect2, varscan2
- MYO18A | c.4782T>A p.D1594E | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.086); catalogued as COSV62866082; called by muse, mutect2, varscan2
- NDST4 | c.2320G>C p.D774H | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as rs775356733, COSV52117642; called by muse, mutect2
- NUP188 | c.4137+1G>A p.X1379_splice | Splice Site (SNP) | VAF 7/45 reads (16%) | catalogued as COSV65361947, COSV65363443; called by muse, mutect2, varscan2
- OAS2 | c.1636G>T p.V546L | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV60802375; called by muse, mutect2, varscan2
- OR52M1 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64171954; called by muse, mutect2
- OR7A10 | c.162C>A p.H54Q | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.342); catalogued as COSV50166285; called by muse, mutect2
- P3H4 | c.1273G>A p.G425S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV62680093, COSV62680537; called by mutect2, varscan2
- PATJ | c.1445C>G p.T482S | Missense Mutation (SNP) | VAF 42/242 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as COSV57161219; called by muse, mutect2, varscan2
- PCDH15 | c.1201C>G p.Q401E | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated (0.74); PolyPhen benign (0.015); catalogued as COSV57304981; called by muse, mutect2
- PDZRN3 | c.812A>G p.D271G | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); catalogued as COSV55198499; called by muse, mutect2, varscan2
- PIK3C2G | c.4036C>T p.L1346F (on ENST00000676171; = p.L1305F on NM_004570.5) | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV56804924, COSV56826926; called by muse, varscan2
- PLA2G2F | c.539A>G p.Y180C | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); catalogued as COSV64279955; called by muse, mutect2, varscan2
- RAPGEF2 | c.2149A>T p.S717C | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52427545; called by muse, mutect2, varscan2
- RBL1 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60329778; called by muse, mutect2, varscan2
- RMC1 | c.394A>G p.I132V | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.024); catalogued as COSV52571766; called by muse, mutect2, varscan2
- RPS6KA6 | c.1466A>G p.D489G | Missense Mutation (SNP) | VAF 151/168 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV53119438; called by muse, mutect2, varscan2
- SCRN1 | c.668C>G p.S223C | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV54130483; called by muse, mutect2, varscan2
- SEMA3D | c.275T>C p.L92P | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs972980958, COSV52392566; called by muse, mutect2
- SGO2 | c.2024G>A p.R675K | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as COSV63415303, COSV63418546; called by muse, mutect2
- SLC17A6 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV54136064; called by muse, mutect2, varscan2
- SLC30A8 | c.825G>A p.M275I | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1404452163, COSV69970303; called by muse, mutect2, varscan2
- SLC30A8 | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 22/40 reads (55%) | catalogued as COSV69970309; called by muse, mutect2, varscan2
- SLC4A10 | c.2418A>T p.L806F (on ENST00000446997 / NM_001354461.2; = p.L776F on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV55776944; called by muse, mutect2, varscan2
- SPAG16 | c.1214+1G>T p.X405_splice | Splice Site (SNP) | VAF 12/82 reads (15%) | catalogued as COSV59091267; called by muse, mutect2, varscan2
- SRP72 | c.768-2A>G p.X256_splice | Splice Site (SNP) | VAF 88/209 reads (42%) | catalogued as COSV100714395, COSV61377637; called by muse, mutect2, varscan2
- SRSF5 | c.508A>T p.N170Y | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV53682419, COSV99384233; called by muse, mutect2, varscan2
- SYCP2L | c.1181C>T p.S394L | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV51652902; called by muse, mutect2, varscan2
- TAS2R10 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53700996; called by muse, mutect2, varscan2
- TBR1 | c.1166A>T p.K389I | Missense Mutation (SNP) | VAF 63/116 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67417772; called by muse, mutect2, varscan2
- TBX3 | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 106/280 reads (38%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV57471248, COSV99983739; called by muse, mutect2, varscan2
- TENM3 | c.2372G>A p.G791E | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1330042105, COSV69307071; called by muse, mutect2
- TERT | c.2221G>T p.V741L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs150819225, COSV99721391; called by mutect2, varscan2
- TRIP11 | c.5842C>G p.L1948V | Missense Mutation (SNP) | VAF 9/221 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.539); catalogued as COSV50920925, COSV99970508; called by muse, mutect2
- TTN | c.93238G>A p.V31080I (on ENST00000591111; = p.V23656I on NM_003319.4) | Missense Mutation (SNP) | VAF 53/119 reads (45%) | PolyPhen possibly damaging (0.528); catalogued as rs533651182, COSV60034958; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBA6 | c.2195-1G>T p.X732_splice | Splice Site (SNP) | VAF 41/125 reads (33%) | catalogued as COSV59176874; called by muse, mutect2, varscan2
- XIRP2 | c.7039C>A p.H2347N (on ENST00000628543; = p.H2522N on NM_152381.6) | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.075); catalogued as COSV54683852, COSV54698097; called by muse, mutect2, varscan2
- ZMYM4 | c.2684C>A p.A895D | Missense Mutation (SNP) | VAF 85/206 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.123); catalogued as COSV58910113; called by muse, mutect2, varscan2
- ZNF202 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV60247030; called by muse, mutect2, varscan2
- CYB561D1 | c.678_680del p.M227del | In Frame Del (DEL) | VAF 39/117 reads (33%) | called by mutect2, pindel, varscan2
- IARS2 | c.1909_1910del p.L637Nfs*12 | Frame Shift Del (DEL) | VAF 43/118 reads (36%) | called by mutect2, pindel, varscan2
- LDB3 | c.1939del p.L647Sfs*56 | Frame Shift Del (DEL) | VAF 20/61 reads (33%) | called by mutect2, pindel, varscan2
- MYO3B | c.2471G>A p.R824K | Missense Mutation (SNP) | VAF 4/85 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.129); called by muse, mutect2
- OR4K2 | c.89T>G p.V30G | Missense Mutation (SNP) | VAF 34/245 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- TADA2A | c.1217A>G p.N406S | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTC21A | c.686A>G p.D229G | Missense Mutation (SNP) | VAF 5/106 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TULP4 | c.22G>T p.G8W | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF658 | c.297G>T p.W99C | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- ADPRH | c.1041C>A p.L347= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as COSV63694916, COSV99053025; called by muse, mutect2, varscan2
- AHNAK2 | c.2622G>A p.G874= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV100317364; called by muse, mutect2, varscan2
- CENPE | c.4920G>A p.Q1640= | Silent (SNP) | VAF 21/36 reads (58%) | catalogued as COSV54380762; called by muse, mutect2, varscan2
- CPAMD8 | c.2376T>C p.T792= (on ENST00000651564; = p.T745= on NM_015692.5) | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV52233965; called by muse, mutect2, varscan2
- CR1L | c.936G>A p.Q312= | Silent (SNP) | VAF 53/383 reads (14%) | catalogued as rs769450277, COSV54325648; called by muse, mutect2, varscan2
- DYTN | c.1335T>C p.N445= | Silent (SNP) | VAF 43/161 reads (27%) | catalogued as rs769051080, COSV71751979; called by muse, mutect2, varscan2
- EPS8 | c.906A>G p.K302= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV104385153, COSV55530355; called by muse, mutect2, varscan2
- ERC2 | c.1203C>T p.I401= | Silent (SNP) | VAF 56/159 reads (35%) | catalogued as COSV55619987; called by muse, mutect2, varscan2
- FAM160A1 | c.456A>T p.G152= | Silent (SNP) | VAF 35/129 reads (27%) | catalogued as COSV101475190, COSV70707078; called by muse, mutect2, varscan2
- FAM47B | c.297G>A p.K99= | Silent (SNP) | VAF 41/81 reads (51%) | catalogued as COSV61452353, COSV61453640; called by muse, mutect2, varscan2
- FLG | c.4173T>C p.S1391= | Silent (SNP) | VAF 60/184 reads (33%) | catalogued as rs762904383, COSV64241444; called by muse, mutect2
- FREM2 | c.4872C>A p.T1624= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as COSV54836734; called by muse, mutect2, varscan2
- GJA9 | c.1509T>C p.N503= | Silent (SNP) | VAF 60/137 reads (44%) | catalogued as COSV62532121; called by muse, mutect2, varscan2
- ILF3 | c.1005C>T p.G335= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV51557182; called by muse, varscan2
- KLB | c.1374T>C p.T458= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as COSV57301588; called by muse, mutect2
- LRRC37B | c.2475C>T p.T825= | Silent (SNP) | VAF 642/1070 reads (60%) | called by muse, varscan2
- LRRC69 | c.675A>G p.E225= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV59251278; called by muse, mutect2, varscan2
- MSMB | c.306C>T p.D102= | Silent (SNP) | VAF 7/98 reads (7%) | called by muse, mutect2
- PRADC1 | c.321C>T p.H107= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs748507079, COSV57820167; called by muse, mutect2
- PRKAA2 | c.1608C>A p.T536= | Silent (SNP) | VAF 38/148 reads (26%) | catalogued as COSV64803559; called by muse, mutect2, varscan2
- RALYL | c.594C>G p.T198= | Silent (SNP) | VAF 17/175 reads (10%) | catalogued as COSV72820407; called by muse, mutect2, varscan2
- RNF213 | c.6654T>C p.F2218= | Silent (SNP) | VAF 16/421 reads (4%) | called by muse, mutect2
- RTL10 | c.747A>G p.V249= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV60735651; called by muse, mutect2, varscan2
- SELENOI | c.661C>T p.L221= | Silent (SNP) | VAF 4/90 reads (4%) | called by muse, mutect2
- SETDB1 | c.87G>A p.V29= | Silent (SNP) | VAF 32/379 reads (8%) | catalogued as COSV54982006; called by muse, mutect2
- TAF3 | c.612G>T p.T204= | Silent (SNP) | VAF 49/137 reads (36%) | catalogued as COSV60203032, COSV60206343; called by muse, mutect2, varscan2
- TMTC2 | c.1419G>A p.R473= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as COSV58267767, COSV58268447; called by muse, mutect2, varscan2
- TRPM2 | c.1554C>T p.T518= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as COSV55969325; called by muse, mutect2, varscan2
- TTN | c.16128C>T p.S5376= (on ENST00000591111; = p.S4449= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as rs372588069, COSV60034992; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- BIRC8 | n.1272G>A | RNA (SNP) | VAF 58/139 reads (42%) | catalogued as rs1225378522, COSV70346796; called by muse, mutect2, varscan2
- FUT9 | c.*9540A>G | 3'UTR (SNP) | VAF 34/62 reads (55%) | catalogued as COSV100134635, COSV56150945, COSV56154245; called by muse, mutect2, varscan2
- KCNJ2 | c.*3033T>G | 3'UTR (SNP) | VAF 21/58 reads (36%) | catalogued as COSV99696579; called by muse, mutect2, varscan2
- LCE2D | c.*28G>T | 3'UTR (SNP) | VAF 31/70 reads (44%) | catalogued as COSV100909627; called by muse, mutect2, varscan2
- NCAPH2 | c.*1203C>A | 3'UTR (SNP) | VAF 12/77 reads (16%) | called by muse, mutect2
- ZNF646 | c.*682T>C | 3'UTR (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
